Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012419-04A.1 (aliquot TARGET-15-SJMPAL012419-04A.1-01D) from TARGET case TARGET-15-SJMPAL012419, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (5,973 days).
Specimen TARGET-15-SJMPAL012419-04A.1: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d53580d4-2185-4d49-b9e0-62d0b2843778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012419-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012419-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a59dfd6b-7f61-4d35-8d35-acaf9bfdf517

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 3, RNA 1, 5'UTR 1, 5'Flank 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXTL1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375730801; called by muse, mutect2, varscan2
- FAM186A | c.3875A>C p.N1292T | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1005894085, COSV59247760; called by muse, mutect2
- KLHL29 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.514); catalogued as rs1044731837, COSV72085708; called by muse, mutect2
- MUC4 | c.5717A>C p.H1906P | Missense Mutation (SNP) | VAF 101/991 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.234); catalogued as rs529505943, COSV62160307, COSV62166080; called by muse, mutect2
- NEU4 | c.547C>T p.R183C (on ENST00000391969 / NM_001167602.3; = p.R195C on NM_080741.4) | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs139467778, COSV100372104; called by muse, mutect2
- PCDHA10 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 203/447 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs782288464, COSV100253124; called by muse, mutect2, varscan2
- RNF20 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66355722; called by muse, mutect2, varscan2
- SEL1L | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs374625468; called by muse, mutect2, varscan2
- THEMIS | c.1643G>T p.S548I | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs780704106, COSV64074696; called by muse, mutect2
- ZNF185 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782347395, COSV59274709; called by muse, mutect2
- ZNF462 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52952732; called by muse, mutect2
- AC138647.1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GRK3 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- N4BP1 | c.1751A>C p.D584A | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRPM2 | c.1437_1438del p.W479* | Nonsense Mutation (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel*
- TUBA4A | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.291); called by muse, mutect2
- XBP1 | c.508_509insCGGC p.R170Pfs*218 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, pindel
- CASP1 | c.831G>A p.P277= (on ENST00000436863 / NM_033292.4; = p.P256= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as rs1456744063, COSV62056501; called by muse, mutect2, varscan2
- IGLV5-45 | c.303C>T p.L101= | Silent (SNP) | VAF 50/286 reads (17%) | called by muse, varscan2
- NAT10 | c.840T>C p.V280= | Silent (SNP) | VAF 72/168 reads (43%) | called by muse, mutect2, varscan2
- PCDHA12 | c.390G>A p.P130= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as COSV100251916; called by muse, mutect2
- USP13 | c.2301C>T p.H767= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1299829596; called by muse, mutect2, varscan2
- ABCB9 | c.2040+19G>A | Intron (SNP) | VAF 30/158 reads (19%) | catalogued as rs543560279; called by muse, mutect2, varscan2
- AL445584.1 | chr9:42199561 G>T | 5'Flank (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- AL669831.1 | n.2639G>C | RNA (SNP) | VAF 13/123 reads (11%) | catalogued as rs369817233; called by mutect2, varscan2
- ANGPTL3 | c.-30C>T | 5'UTR (SNP) | VAF 44/126 reads (35%) | catalogued as rs769920975; called by mutect2, varscan2
- CYBC1 | c.*187G>A | 3'UTR (SNP) | VAF 16/307 reads (5%) | catalogued as rs972420992, COSV60065219; called by muse, mutect2
- IGF2BP2 | c.240-18266C>T | Intron (SNP) | VAF 20/157 reads (13%) | catalogued as rs375339425; called by muse, mutect2, varscan2
- MARCHF8 | c.242+691G>A | Intron (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
